Somatic mutation profile of tumor specimen TCGA-A3-3383-01A (aliquot TCGA-A3-3383-01A-01W-0886-08) from TCGA case TCGA-A3-3383, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 52.9 years (19,324 days).
Specimen TCGA-A3-3383-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66538a84-e030-4f21-b05b-a0ad20c8ed27.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3383-11A (Solid Tissue Normal), aliquot TCGA-A3-3383-11A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20b44cad-29c5-4bd0-88cb-d0e86bb12654

The open-access MAF lists 62 somatic variants for this specimen: 52 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 33, Silent 10, Frame Shift Ins 6, Frame Shift Del 6, Nonsense Mutation 3, In Frame Del 2, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANTXR2 | c.1073dup p.A359Cfs*13 | Frame Shift Ins (INS) | VAF 5/42 reads (12%) | catalogued as rs312262690; ClinVar: pathogenic; called by pindel, varscan2
- VHL | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 23/71 reads (32%) | hotspot (GDC flag); catalogued as rs5030818, CM941381, CM961432, COSV56542817, COSV56554019, COSV56564848; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BTNL3 | c.1200dup p.S401Qfs*14 | Frame Shift Ins (INS) | VAF 13/118 reads (11%) | catalogued as rs757227190; called by mutect2, varscan2
- COL11A2 | c.2818G>T p.G940W (on ENST00000341947 / NM_080680.3; = p.G833W on NM_080679.2) | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100554612; called by muse, mutect2, varscan2
- COL5A3 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs144021089; called by muse, mutect2, varscan2
- NEURL3 | c.620A>G p.Y207C | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1227121165; called by muse, mutect2, varscan2
- NUP205 | c.4465C>T p.H1489Y | Missense Mutation (SNP) | VAF 46/200 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767069832; called by muse, mutect2, varscan2
- PCF11 | c.1786A>G p.R596G | Missense Mutation (SNP) | VAF 53/215 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53530551, COSV53532229; called by muse, mutect2, varscan2
- SETD2 | c.3964C>T p.R1322* | Nonsense Mutation (SNP) | VAF 66/187 reads (35%) | catalogued as COSV57441467; called by muse, mutect2, varscan2
- SHROOM2 | c.4663C>T p.R1555C | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66604484; called by muse, mutect2, varscan2
- SLIT2 | c.3641G>A p.R1214H | Missense Mutation (SNP) | VAF 94/223 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs757958276, COSV56578826; called by muse, mutect2, varscan2
- TET3 | c.5243dup p.T1749Hfs*5 | Frame Shift Ins (INS) | VAF 9/45 reads (20%) | catalogued as rs759623160; called by mutect2, varscan2
- TFE3 | c.1445dup p.P483Tfs*138 | Frame Shift Ins (INS) | VAF 38/226 reads (17%) | catalogued as rs782753958; called by mutect2, varscan2
- TRIM3 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 60/199 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs779125524; called by muse, mutect2, varscan2
- ACLY | c.2845G>A p.A949T | Missense Mutation (SNP) | VAF 53/176 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- CFAP251 | c.806A>T p.E269V | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- COPB2 | c.1164del p.F388Lfs*18 | Frame Shift Del (DEL) | VAF 108/380 reads (28%) | called by mutect2, pindel, varscan2
- CRYBG1 | c.6154_6156delinsA p.C2052Tfs*23 | Frame Shift Del (DEL) | VAF 48/194 reads (25%) | called by pindel, varscan2*
- CSTF3 | c.782G>A p.S261N | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CTPS1 | c.1264A>G p.T422A | Missense Mutation (SNP) | VAF 45/180 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- DOCK4 | c.1118G>A p.R373K | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EYA2 | c.947_949del p.A316del | In Frame Del (DEL) | VAF 22/162 reads (14%) | called by mutect2, pindel, varscan2
- FCAR | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- GLS2 | c.776A>C p.E259A | Missense Mutation (SNP) | VAF 22/478 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.038); called by muse, mutect2
- GPR158 | c.3241A>C p.I1081L | Missense Mutation (SNP) | VAF 84/302 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRHL1 | c.577G>C p.D193H | Missense Mutation (SNP) | VAF 62/231 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- GRPEL1 | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 54/220 reads (25%) | called by muse, mutect2, varscan2
- HEPH | c.298G>A p.G100R (on ENST00000343002; = p.G154R on NM_138737.5) | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- ITPR2 | c.974C>G p.A325G | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITPR2 | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MYH2 | c.1266+2T>C p.X422_splice | Splice Site (SNP) | VAF 106/383 reads (28%) | called by muse, mutect2, varscan2
- NCAPH2 | c.109-2A>C p.X37_splice | Splice Site (SNP) | VAF 12/70 reads (17%) | called by muse, varscan2
- NUP133 | c.2302_2312del p.T768Wfs*12 | Frame Shift Del (DEL) | VAF 26/218 reads (12%) | called by mutect2, pindel
- OR8G1 | c.724A>T p.S242C | Missense Mutation (SNP) | VAF 121/432 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- OR8G1 | c.725G>A p.S242N | Missense Mutation (SNP) | VAF 121/427 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- PBRM1 | c.329del p.N110Ifs*3 | Frame Shift Del (DEL) | VAF 20/61 reads (33%) | called by mutect2, pindel, varscan2
- PITX2 | c.646T>A p.S216T (on ENST00000354925 / NM_001204397.1; = p.S223T on NM_000325.6) | Missense Mutation (SNP) | VAF 70/239 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- POM121C | c.1303G>C p.E435Q (on ENST00000607367; = p.E193Q on NM_001099415.3) | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- PPM1B | c.1206T>G p.N402K | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- RBBP6 | c.344C>A p.T115K | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- RBM43 | c.162A>G p.I54M | Missense Mutation (SNP) | VAF 69/226 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- RHOBTB1 | c.235T>A p.S79T | Missense Mutation (SNP) | VAF 48/173 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- RPE65 | c.1191dup p.D398* | Frame Shift Ins (INS) | VAF 39/149 reads (26%) | called by mutect2, pindel, varscan2
- TAF3 | c.619G>T p.V207F | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.08); called by muse, mutect2
- TDRD9 | c.4086_4094del p.S1363_R1365del | In Frame Del (DEL) | VAF 6/46 reads (13%) | called by mutect2, pindel
- TRIM33 | c.1820G>T p.G607V | Missense Mutation (SNP) | VAF 78/249 reads (31%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- TSHZ2 | c.419G>A p.G140D | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.617); called by muse, mutect2
- WDR46 | c.952G>A p.G318R | Missense Mutation (SNP) | VAF 66/246 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDR83 | c.650T>A p.L217H | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZKSCAN3 | c.1561del p.S521Hfs*11 | Frame Shift Del (DEL) | VAF 105/332 reads (32%) | called by mutect2, pindel, varscan2
- ZNF600 | c.132del p.I44Mfs*17 | Frame Shift Del (DEL) | VAF 218/810 reads (27%) | called by mutect2, pindel, varscan2
- ZNF646 | c.2106dup p.E703* | Frame Shift Ins (INS) | VAF 8/40 reads (20%) | called by mutect2, pindel, varscan2
- ASCC3 | c.3453G>T p.L1151= | Silent (SNP) | VAF 9/98 reads (9%) | called by muse, mutect2, varscan2
- BUB1B | c.2658G>A p.R886= | Silent (SNP) | VAF 49/145 reads (34%) | called by muse, mutect2, varscan2
- DNAJB12 | c.798G>A p.R266= (on ENST00000338820; = p.R232= on NM_017626.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 20/55 reads (36%) | called by muse, mutect2, varscan2
- GRID1 | c.342C>G p.L114= | Silent (SNP) | VAF 59/195 reads (30%) | called by muse, mutect2, varscan2
- LDLR | c.1530G>A p.T510= | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as rs367655096, CD005364; ClinVar: likely benign; called by muse, mutect2, varscan2
- MAEA | c.237C>T p.S79= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as rs199554247; called by muse, mutect2, varscan2
- NUP153 | c.1257A>G p.E419= | Silent (SNP) | VAF 98/259 reads (38%) | called by muse, mutect2, varscan2
- STYK1 | c.357G>A p.Q119= | Silent (SNP) | VAF 10/174 reads (6%) | called by muse, mutect2
- TMEM214 | c.174C>A p.T58= | Silent (SNP) | VAF 106/291 reads (36%) | called by muse, mutect2, varscan2
- UXS1 | c.930G>T p.V310= | Silent (SNP) | VAF 55/390 reads (14%) | called by muse, mutect2, varscan2
